TCGA case TCGA-SC-A6LQ — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/500b86b2-3ac3-4745-af84-3dd28f38daeb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Dead; Days to death: 297 days.

Diagnoses (2)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 60.3 years (22,014 days); Year of diagnosis: 2012; Method of diagnosis: Thoracentesis; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed; Days to treatment start: 74 days; Days to treatment end: 137 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 169 days; Days to treatment end: 209 days; Treatment dose: 5,040 cGy; Treatment outcome: Stable Disease; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.
2. Metastasis of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Abdomen, NOS. Age at diagnosis: 60.9 years (22,252 days); Days to diagnosis: 238 days; Prior treatment: Yes.

Follow-up (3 entries)
- Day 238 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 238 days.
- Days to follow up: 297 days; Disease response: With Tumor.
- Imaging anatomic site: Pleura; Imaging suv max: 3.2; Timepoint: Prior to Treatment.

Molecular and laboratory tests
- Creatinine 0.7 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1.3].

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-SC-A6LQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 450 mg.
  Slide TCGA-SC-A6LQ-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-SC-A6LQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SC-A6LQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: No.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 297 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 297 days; disease-free interval: event (new tumor event after initially disease-free), 238 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 238 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SC-A6LQ-01A-11D-A34B-01): tumor purity 0.42, ploidy 1.9, whole-genome doublings 0.
